Somatic mutation profile of tumor specimen TCGA-AB-2813-03B (aliquot TCGA-AB-2813-03B-01W-0728-08) from TCGA case TCGA-AB-2813, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 78.3 years (28,581 days).
Specimen TCGA-AB-2813-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e947342-c43b-4038-9410-3669caca9175.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2813-11B (Solid Tissue Normal), aliquot TCGA-AB-2813-11B-01W-0728-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06a0c367-e314-4007-a609-fbe4e04f59d8

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 89/116 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- BBS12 | c.1571A>G p.Y524C | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as rs770746493, CM101930, COSV58562201; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1B | c.6926G>A p.R2309H | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs199734998, COSV53128455; called by muse, mutect2, varscan2
- DLD | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52738235; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1111C>A p.L371I | Missense Mutation (SNP) | VAF 24/498 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.245); catalogued as COSV100145861; called by muse, mutect2
- IQCN | c.1432A>G p.K478E | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV66574654; called by muse, mutect2, varscan2
- NKRF | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs929416337, COSV58661733; called by muse, mutect2, varscan2
- SLC38A6 | c.937T>A p.S313T | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.231); catalogued as COSV50782782; called by muse, mutect2, varscan2
- SLC22A10 | c.1480del p.T494Pfs*60 | Frame Shift Del (DEL) | VAF 140/464 reads (30%) | called by pindel, varscan2
- FAT3 | c.6111G>T p.T2037= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV53118999; called by mutect2, varscan2
- GNPTAB | c.396C>T p.H132= | Silent (SNP) | VAF 34/99 reads (34%) | catalogued as COSV71820762; called by muse, mutect2, varscan2
- HK1 | c.2427G>T p.L809= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV53853647, COSV53859252; called by muse, mutect2
